Somatic mutation profile of tumor specimen TCGA-06-1804-01A (aliquot TCGA-06-1804-01A-01D-1696-08) from TCGA case TCGA-06-1804, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 81.6 years (29,802 days).
Specimen TCGA-06-1804-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1762f3fa-9cab-427b-b36c-82364dd883c9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-1804-10A (Blood Derived Normal), aliquot TCGA-06-1804-10A-01D-1696-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3a922b8a-c15a-4623-814a-e54ede09339c

The open-access MAF lists 85 somatic variants for this specimen: 57 protein-altering or splice-affecting, 24 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 51, Silent 24, Nonsense Mutation 4, Intron 2, RNA 2, Splice Site 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC10 | c.1708C>T p.R570W (on ENST00000372530 / NM_001198934.2; = p.R527W on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/117 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1376706540, COSV55085131; called by muse, mutect2, varscan2
- PTEN | c.131G>A p.G44D | Missense Mutation (SNP) | VAF 13/17 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1085308042, CM090865, COSV64291362; ClinVar: pathogenic; called by muse, varscan2
- ABCA3 | c.614G>A p.G205E | Missense Mutation (SNP) | VAF 56/128 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs748051185, COSV57050225; called by muse, mutect2, varscan2
- ADAM28 | c.1899C>A p.C633* | Nonsense Mutation (SNP) | VAF 16/30 reads (53%) | catalogued as COSV56098355; called by muse, mutect2, varscan2
- ADGRG5 | c.1541C>T p.A514V | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.033); catalogued as COSV61082683; called by muse, mutect2, varscan2
- ANK2 | c.7430A>T p.K2477M | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.939); catalogued as COSV52149033; called by muse, mutect2, varscan2
- CARMIL3 | c.3853A>G p.R1285G | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.966); catalogued as rs1477636143, COSV53742799; called by muse, mutect2, varscan2
- CCDC68 | c.368G>A p.G123E | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765362415, COSV61603168; called by muse, mutect2, varscan2
- CD53 | c.449C>T p.T150M | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.81); catalogued as rs369006161, COSV54760274; called by muse, mutect2, varscan2
- CDH9 | c.1655G>A p.R552Q | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.354); catalogued as rs150128137, COSV99142617; called by muse, mutect2, varscan2
- CEP170B | c.3063G>A p.M1021I (on ENST00000453495; = p.M950I on NM_015005.3) | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.009); catalogued as COSV69026973; called by muse, mutect2, varscan2
- CFAP54 | c.5350C>A p.P1784T | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61570947; called by muse, mutect2, varscan2
- COL6A3 | c.5133C>G p.Y1711* | Nonsense Mutation (SNP) | VAF 25/68 reads (37%) | catalogued as COSV55081727; called by muse, mutect2, varscan2
- DDB1 | c.2127G>C p.K709N | Missense Mutation (SNP) | VAF 112/335 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV57101352; called by muse, mutect2, varscan2
- EGFR | c.766G>T p.D256Y | Missense Mutation (SNP) | VAF 27/185 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV51855357; called by muse, mutect2, varscan2
- ERC1 | c.1892G>A p.R631H (on ENST00000360905 / NM_178040.4; = p.R603H on NM_178039.4) | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.98); catalogued as rs138512011; called by muse, mutect2, varscan2
- FAM71B | c.1793T>C p.I598T | Missense Mutation (SNP) | VAF 160/417 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV57227812; called by muse, mutect2, varscan2
- FOXJ2 | c.64G>A p.A22T | Missense Mutation (SNP) | VAF 15/175 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV50826064; called by muse, mutect2
- GGA2 | c.177-1G>A p.X59_splice | Splice Site (SNP) | VAF 8/126 reads (6%) | catalogued as COSV59170829; called by muse, mutect2
- GJB4 | c.481G>A p.V161M | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.435); catalogued as rs566099103, COSV58355536; called by muse, mutect2, varscan2
- GPR6 | c.92C>T p.P31L | Missense Mutation (SNP) | VAF 45/106 reads (42%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); catalogued as rs768568157, COSV51571170; called by muse, mutect2, varscan2
- HRH3 | c.626C>T p.T209M | Missense Mutation (SNP) | VAF 64/149 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.701); catalogued as rs1204125626, COSV58047775; called by muse, mutect2, varscan2
- HTR3E | c.1003G>A p.V335M (on ENST00000415389 / NM_001256613.1; = p.V350M on NM_182589.2) | Missense Mutation (SNP) | VAF 62/168 reads (37%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.748); catalogued as rs1202055797, COSV58946033; called by muse, mutect2, varscan2
- ICE1 | c.5186G>T p.G1729V | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56833965; called by muse, mutect2, varscan2
- ITM2C | c.391G>A p.V131M | Missense Mutation (SNP) | VAF 100/247 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs753559957, COSV58398630; called by muse, mutect2, varscan2
- LARP4 | c.611G>A p.R204K | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); catalogued as COSV53320219; called by muse, mutect2, varscan2
- MYL10 | c.599C>T p.A200V | Missense Mutation (SNP) | VAF 50/214 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.088); catalogued as rs1444281088, COSV56207261; called by muse, mutect2, varscan2
- NLRP6 | c.2587G>T p.A863S | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (0.22); PolyPhen benign (0.017); catalogued as COSV56458462; called by muse, mutect2, varscan2
- NPAS4 | c.611G>A p.G204D | Missense Mutation (SNP) | VAF 57/140 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.102); catalogued as COSV60649116; called by muse, mutect2, varscan2
- OR4D6 | c.4G>T p.D2Y | Missense Mutation (SNP) | VAF 52/140 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.139); catalogued as rs1295407155, COSV100271922, COSV55659140; called by muse, mutect2, varscan2
- OR51A2 | c.310T>A p.F104I | Missense Mutation (SNP) | VAF 43/52 reads (83%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV66748177; called by muse, mutect2, varscan2
- OR52E2 | c.563A>G p.H188R | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58611969; called by muse, mutect2, varscan2
- PAX6 | c.56G>T p.R19L | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM030485, COSV53795953; called by muse, mutect2
- PEX5L | c.1435G>A p.G479S | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55840499; called by muse, mutect2, varscan2
- PIKFYVE | c.1885C>G p.L629V | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); catalogued as COSV52250207; called by muse, mutect2
- PKHD1 | c.11027G>A p.G3676E | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as COSV64382797; called by muse, mutect2, varscan2
- PLCH1 | c.2830G>A p.D944N (on ENST00000340059 / NM_001130960.2; = p.D936N on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/94 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as COSV58189158; called by muse, mutect2, varscan2
- POF1B | c.214C>T p.R72W | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.534); catalogued as COSV53141622; called by muse, mutect2, varscan2
- RBM46 | c.379C>T p.R127* | Nonsense Mutation (SNP) | VAF 18/45 reads (40%) | catalogued as rs866164836, COSV55977357; called by muse, mutect2, varscan2
- RESF1 | c.4150G>C p.D1384H | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV57026380; called by muse, mutect2, varscan2
- RIT1 | c.633C>G p.F211L | Missense Mutation (SNP) | VAF 94/271 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV64170907; called by muse, mutect2, varscan2
- RTN2 | c.179G>A p.R60Q | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs1255784159, COSV55592530; called by muse, mutect2, varscan2
- SLAMF1 | c.322C>T p.R108W | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as rs374126308; called by muse, mutect2, varscan2
- SLC16A5 | c.1016G>A p.S339N | Missense Mutation (SNP) | VAF 375/937 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV61675469; called by muse, mutect2, varscan2
- SLC9A7 | c.254T>A p.I85N | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV60378283; called by muse, mutect2, varscan2
- SPAG17 | c.4220G>T p.G1407V | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60454052; called by muse, mutect2, varscan2
- SPATA31D1 | c.4109A>G p.E1370G | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV61202262; called by muse, mutect2, varscan2
- SYBU | c.886G>T p.E296* (on ENST00000276646 / NM_001099754.2; = p.E295* on NM_017786.6) | Nonsense Mutation (SNP) | VAF 25/52 reads (48%) | catalogued as COSV52614919, COSV99405873; called by muse, mutect2, varscan2
- TENM4 | c.7356C>G p.F2452L | Missense Mutation (SNP) | VAF 41/126 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV53677510; called by muse, mutect2, varscan2
- TGS1 | c.908A>G p.D303G | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs1354356799, COSV52698641; called by muse, mutect2, varscan2
- TNS1 | c.867C>A p.F289L | Missense Mutation (SNP) | VAF 46/114 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV50692293; called by muse, mutect2, varscan2
- TRIOBP | c.1061C>A p.P354H | Missense Mutation (SNP) | VAF 108/176 reads (61%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.533); catalogued as rs559855483, COSV60374369; called by muse, mutect2, varscan2
- UBE3C | c.2818C>T p.R940C | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs142140245; called by muse, mutect2, varscan2
- UNKL | c.1819G>A p.E607K | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs931049023, COSV50190982; called by muse, mutect2, varscan2
- ZNF292 | c.145G>T p.D49Y | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV60548088; called by muse, mutect2
- ZNF442 | c.1378C>T p.P460S | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as rs971393880, COSV54420629; called by muse, mutect2, varscan2
- CCL14 | c.79+1G>T p.X27_splice | Splice Site (SNP) | VAF 30/77 reads (39%) | called by muse, mutect2, varscan2
- ATP13A2 | c.2400G>A p.V800= | Silent (SNP) | VAF 43/128 reads (34%) | catalogued as COSV58698534; called by muse, mutect2, varscan2
- ATP2B2 | c.2667G>A p.T889= (on ENST00000352432; = p.T855= on NM_001683.5) | Silent (SNP) | VAF 16/77 reads (21%) | catalogued as rs779409545, COSV59490628; called by muse, mutect2, varscan2
- CACNA1B | c.2142C>T p.N714= | Silent (SNP) | VAF 33/100 reads (33%) | catalogued as rs570622319, COSV53119959; called by muse, mutect2, varscan2
- CD6 | c.45C>A p.L15= | Silent (SNP) | VAF 20/45 reads (44%) | catalogued as COSV57836229; called by muse, mutect2, varscan2
- CETP | c.1374C>T p.F458= | Silent (SNP) | VAF 67/139 reads (48%) | catalogued as rs544041690, COSV52361670, COSV52363323; called by muse, mutect2, varscan2
- CFAP92 | c.708A>G p.E236= | Silent (SNP) | VAF 49/132 reads (37%) | catalogued as COSV54049268; called by muse, mutect2, varscan2
- CLDN18 | c.33C>T p.F11= | Silent (SNP) | VAF 54/174 reads (31%) | catalogued as COSV59301692; called by muse, mutect2, varscan2
- DOCK5 | c.2661C>T p.S887= | Silent (SNP) | VAF 56/162 reads (35%) | catalogued as rs746351602, COSV52396952; called by muse, mutect2, varscan2
- ENGASE | c.1746C>T p.L582= | Silent (SNP) | VAF 12/83 reads (14%) | catalogued as rs755973878, COSV56138158; called by muse, mutect2, varscan2
- ERN1 | c.807G>A p.P269= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as rs183713088; called by muse, mutect2, varscan2
- FLG | c.11721C>T p.R3907= | Silent (SNP) | VAF 39/107 reads (36%) | catalogued as rs374091552; called by muse, mutect2, varscan2
- GRIN2A | c.57C>T p.R19= | Silent (SNP) | VAF 13/79 reads (16%) | catalogued as rs1443213122, COSV58059234; called by muse, mutect2, varscan2
- GUCY1A1 | c.702G>A p.S234= | Silent (SNP) | VAF 17/52 reads (33%) | catalogued as rs545740746, COSV56649683; called by muse, mutect2, varscan2
- IL2 | c.330C>T p.N110= | Silent (SNP) | VAF 9/20 reads (45%) | catalogued as COSV56985426; called by muse, mutect2, varscan2
- IQGAP3 | c.3831C>T p.P1277= | Silent (SNP) | VAF 51/134 reads (38%) | catalogued as COSV63249925; called by muse, mutect2, varscan2
- KIF17 | c.2319C>T p.Y773= | Silent (SNP) | VAF 55/143 reads (38%) | catalogued as rs373972661; called by muse, mutect2, varscan2
- MS4A8 | c.312C>T p.Y104= | Silent (SNP) | VAF 80/211 reads (38%) | catalogued as rs144254483, COSV55753762; called by muse, mutect2, varscan2
- MYO3A | c.567G>A p.P189= | Silent (SNP) | VAF 12/22 reads (55%) | catalogued as rs1379413436, COSV56321859; called by muse, mutect2, varscan2
- OSBPL8 | c.1296C>T p.P432= | Silent (SNP) | VAF 22/69 reads (32%) | catalogued as COSV53879046; called by muse, mutect2, varscan2
- PCDHA12 | c.1614C>T p.R538= | Silent (SNP) | VAF 108/275 reads (39%) | catalogued as COSV56502265; called by muse, mutect2, varscan2
- PHEX | c.765T>C p.D255= | Silent (SNP) | VAF 10/156 reads (6%) | catalogued as rs1411877524, COSV65079616; called by muse, mutect2
- PPP2R2B | c.540T>A p.S180= (on ENST00000394409; = p.S246= on NM_181674.2) | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as rs146742970; called by muse, mutect2, varscan2
- SULF2 | c.723C>T p.N241= | Silent (SNP) | VAF 39/88 reads (44%) | catalogued as rs762972808, COSV63413882, COSV63420555; called by muse, mutect2, varscan2
- TRPM4 | c.1599C>T p.F533= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as COSV53269602; called by muse, mutect2, varscan2
- FBXL13 | c.496-5481G>A | Intron (SNP) | VAF 47/226 reads (21%) | catalogued as rs776326891, COSV100501351; called by muse, mutect2, varscan2
- FOLH1B | n.1060C>G | RNA (SNP) | VAF 19/46 reads (41%) | called by muse, mutect2, varscan2
- MAGEA5 | n.328A>T | RNA (SNP) | VAF 91/231 reads (39%) | called by muse, mutect2, varscan2
- RBFOX1 | c.28-185085G>A | Intron (SNP) | VAF 35/119 reads (29%) | catalogued as rs1325337150, COSV60948471; called by muse, mutect2, varscan2
